TCGA case TCGA-50-8459 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9cfc1519-33e7-4145-a4ad-78b5c449853a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C34.30; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,859 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Cisplatin + Pemetrexed Disodium; Days to treatment start: 76 days; Days to treatment end: 147 days; Treatment outcome: Complete Response; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Mucinous adenocarcinoma). Age at diagnosis: 69.2 years (25,291 days); Days to diagnosis: 432 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 432 days (1.2 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 231 days; Disease response: With Tumor.
- Day 432 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 432 days (1.2 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 589 days (1.6 years); Disease response: With Tumor.
- Days to follow up: 1,119 days (3.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- KRAS substitution: Positive; Amino-acid change: G12C.

Other clinical attributes
- DLCO (% of predicted): 70; FEV1/FVC before bronchodilator (%): 70; FEV1 before bronchodilator (% of reference): 72.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 10.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-50-8459-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-50-8459-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 5.
  Slide TCGA-50-8459-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 15.
- Sample TCGA-50-8459-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-50-8459-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-50-8459-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Mucinous (Colloid) Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Lower; KRAS mutation found: Yes; KRAS gene analysis indicator: Yes; KRAS mutation identified type: G12C; EGFR mutation status: Yes; Pulmonary function test indicator: Yes; Treatment outcome first course: Progressive Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: Alimta.
- Drug treatment 3: Pharmaceutical therapy drug name: Avastin.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,119 days; disease-specific survival: no event (censored), 1,119 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 432 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-50-8459-01A-11D-2322-01): tumor purity 0.29, ploidy 1.9, whole-genome doublings 0.
